Somatic mutation profile of tumor specimen TCGA-4V-A9QI-01A (aliquot TCGA-4V-A9QI-01A-11D-A423-09) from TCGA case TCGA-4V-A9QI, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 68.9 years (25,181 days).
Specimen TCGA-4V-A9QI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24947fe5-8fa5-4243-8fc3-0f810751be08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4V-A9QI-10A (Blood Derived Normal), aliquot TCGA-4V-A9QI-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec6f0f31-aec3-4572-bd31-c39fe7e5bf9f

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USP6 | c.2306A>C p.D769A | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.082); catalogued as rs1224435711; called by muse, mutect2
- PEX5 | c.1490T>C p.L497P (on ENST00000420616; = p.L489P on NM_000319.5) | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF14 | c.4806A>G p.K1602= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
